Somatic mutation profile of tumor specimen 0DVZEK from CCDI case PBCNIR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 2.0 years (722 days).
Specimen 0DVZEK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a522272b-837b-45d6-a79d-98dbda5e4b0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZEE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0af1b00-bea7-4bc2-91f6-773ce252fff7

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 3, Frame Shift Ins 1, 5'UTR 1, RNA 1, Splice Region 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.204+3_204+6del p.X68_splice | Splice Site (DEL) | VAF 126/226 reads (56%) | catalogued as rs1567814632; ClinVar: pathogenic; called by mutect2, varscan2
- ADRA1A | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 192/1140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938487720, COSV52362588; called by muse, mutect2, varscan2
- CD6 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 247/393 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs778444894, COSV57842489; called by muse, mutect2, varscan2
- CHAT | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 125/1295 reads (10%) | catalogued as rs777679246; called by muse, mutect2
- DPY19L4 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 181/1056 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as rs1292709205; called by muse, mutect2, varscan2
- GJD2 | c.351C>A p.D117E | Missense Mutation (SNP) | VAF 36/772 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV51748024; called by muse, mutect2
- OR12D3 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 79/776 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs759920431; called by muse, mutect2, varscan2
- OR1F1 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 125/429 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58962391; called by muse, mutect2, varscan2
- ROBO1 | c.661C>G p.R221G | Missense Mutation (SNP) | VAF 39/744 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71392523; called by muse, mutect2
- RUBCNL | c.1122C>G p.V374= | Splice Region (SNP) | VAF 48/560 reads (9%) | catalogued as COSV59790659; called by muse, mutect2
- SLC25A48 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 74/637 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs759243159; called by muse, mutect2, varscan2
- SRPK1 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 24/725 reads (3%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.508); catalogued as COSV60413312; called by muse, mutect2
- TSR3 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 149/459 reads (32%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.001); catalogued as rs774173965; called by muse, mutect2, varscan2
- ARSK | c.477dup p.M160Hfs*3 | Frame Shift Ins (INS) | VAF 146/1158 reads (13%) | called by mutect2, varscan2
- BMP1 | c.2141G>T p.C714F | Missense Mutation (SNP) | VAF 104/1596 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CDC16 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 33/1019 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.765); called by muse, mutect2
- CLTCL1 | c.4264C>A p.L1422M | Missense Mutation (SNP) | VAF 234/656 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COBLL1 | c.2578G>T p.A860S (on ENST00000392717; = p.A822S on NM_014900.5) | Missense Mutation (SNP) | VAF 42/1154 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2
- DTHD1 | c.2057C>A p.A686D (on ENST00000456874; = p.A521D on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/743 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- GRAMD1C | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 145/495 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLB1 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 143/532 reads (27%) | called by muse, mutect2, varscan2
- RBP3 | c.2947G>T p.E983* | Nonsense Mutation (SNP) | VAF 61/592 reads (10%) | called by muse, mutect2, varscan2
- RORB | c.564G>T p.Q188H (on ENST00000396204 / NM_001365023.1; = p.Q177H on NM_006914.4) | Missense Mutation (SNP) | VAF 30/477 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- TAOK3 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 153/746 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- UPF3B | c.1364C>T p.P455L (on ENST00000276201 / NM_080632.3; = p.P442L on NM_023010.3) | Missense Mutation (SNP) | VAF 58/402 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WASHC5 | c.1654G>T p.G552W | Missense Mutation (SNP) | VAF 61/1453 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEACAM6 | c.663G>A p.A221= | Silent (SNP) | VAF 96/454 reads (21%) | catalogued as rs782339128; called by muse, mutect2, varscan2
- CPT1A | c.1407C>T p.L469= | Silent (SNP) | VAF 43/738 reads (6%) | catalogued as COSV55758696; called by muse, mutect2
- KANK1 | c.1329C>T p.A443= | Silent (SNP) | VAF 164/604 reads (27%) | called by muse, mutect2
- PCDHA1 | c.1839G>A p.P613= | Silent (SNP) | VAF 79/713 reads (11%) | catalogued as COSV65373989; called by muse, mutect2, varscan2
- PKD1 | c.10101C>A p.I3367= | Silent (SNP) | VAF 40/580 reads (7%) | called by muse, mutect2
- RP1L1 | c.5154G>A p.T1718= | Silent (SNP) | VAF 40/448 reads (9%) | catalogued as rs767002915, COSV66755139; called by muse, mutect2
- B3GAT1-DT | n.804C>A | RNA (SNP) | VAF 34/615 reads (6%) | called by muse, mutect2
- KCNS2 | c.-16G>A | 5'UTR (SNP) | VAF 46/822 reads (6%) | catalogued as rs958612073, COSV54638698; called by muse, mutect2
- TOX4 | c.319-46G>T | Intron (SNP) | VAF 95/280 reads (34%) | catalogued as rs746790535, COSV52968415; called by muse, mutect2, varscan2
